Gene-level copy-number profile of tumor specimen TCGA-FD-A5BU-01A from TCGA case TCGA-FD-A5BU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 76.3 years (27,882 days).
Specimen TCGA-FD-A5BU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.bccc434c-68af-42e1-b10d-d7b24a13ac30.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A5BU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4a25054-ef21-4a29-b21c-d7c5a25169d3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 81; copy number 2: 5,126; copy number 4: 46,015; copy number 6: 7,328; copy number 7: 30; copy number 8: 135; copy number 9: 1,105.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A5BU-01A-31D-A26L-01): tumor purity 0.4, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:174,820,027–174,995,513, 5 genes: AC113346.1, LINC01951, NIFKP2, AC008413.1, AC008413.2.
- chr9:20,331,446–23,438,700, 70 genes (within-gene range 0–6) (broad region; genes not listed).
- chr9:98,847,172–99,154,192, 6 genes: AL136084.1, NME2P3, COL15A1, AL136084.2, TGFBR1, RNA5SP290.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,105 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,944,428–193,782,758, 813 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr16:80,736,360–90,222,851, 292 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
